TCGA case TCGA-D6-8568 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Larynx; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5ed786f3-1d15-4079-bb8f-2f34ef305644

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, keratinizing, NOS: ICD-O-3 morphology code: 8071/3; ICD-10 code: C32.9; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 62.4 years (22,796 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC clinical T: T2; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage II; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 759 days (2.1 years).
   Pathology details: Consistent pathology review: Yes; Extranodal extension: No Extranodal Extension; Lymph nodes positive: 0; Lymph nodes tested: 3; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Stable Disease.
   Treatment given: Treatment type: Surgery, NOS; Treatment intent type: Cure; Days to treatment end: 0 days; Treatment outcome: No Measurable Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 106 days; Disease response: With Tumor.
- Days to follow up: 759 days (2.1 years); Disease response: Tumor Free.

Exposures
- Alcohol history: Yes; Alcohol drinks per day: 5; Alcohol days per week: 2.
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 43; Tobacco smoking onset year: 1969.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D6-8568-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.8; Intermediate dimension: 0.7; Shortest dimension: 0.5.
  Slide TCGA-D6-8568-01A-01-TS1: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 25; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 10.
  Slide TCGA-D6-8568-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 45; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 15.
- Sample TCGA-D6-8568-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D6-8568-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Lymphovascular invasion: No; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 2; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response; Definitive treatment method: Surgery; Definitive treatment evidence disease after: No; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 759 days; disease-specific survival: no event (censored), 759 days; progression-free interval: no event (censored), 759 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D6-8568-01A-11D-2390-01): tumor purity 0.38, ploidy 2.08, whole-genome doublings 0.
